Surgical pathology report (de-identified scan), TCGA case TCGA-BA-5556, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-5556-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Diagnosis:

FSA: Left tongue base, biopsy

- No dysplasia or carcinoma identified.

FSB: Midline deep margin, biopsy

- Skeletal muscle only, no invasive carcinoma identified.

FSC: Right posterior tongue mucosal margin, biopsy

- No dysplasia or invasive carcinoma identified.

FSD: Right floor of mouth, anterior margin, biopsy

- No dysplasia or invasive carcinoma identified.

FSE: Right mid tongue mucosal margin, biopsy

- No dysplasia or invasive carcinoma identified.

FSF: Left mid lateral tongue mucosa, biopsy

- No dysplasia or invasive carcinoma identified.

FSG: Anterior left floor of mouth mucosa, adjacent to tooth #21, biopsy

- Scant benign squamous epithelium with orthohyperkeratotic debris, without dysplasia.

- No submucosal stroma for evaluation.

FSH: Left posterior tongue mucosa, biopsy

- No dysplasia or invasive carcinoma identified.

FSI: Midline anterior floor of mouth mucosa, biopsy

- Benign squamous mucosa and submucosa with extensive cautery artifact, no dysplasia or invasive carcinoma identified.

J: Lymph node, left neck level 2, dissection

- No metastatic carcinoma identified (0/14).

K: Lymph node, left neck level 3, dissection

- No metastatic carcinoma identified (0/8).

L: Lymph node, left neck level 4, dissection

- No metastatic carcinoma identified (0/11).

M: Bilateral neck, level 1A, dissection

- No metastatic carcinoma identified (0/2).

N: Lymph node, level 1B, dissection

- No metastatic carcinoma identified (0/6).

- Submandibular gland, no carcinoma identified.

O: Lymph node, right neck, level 1B, dissection

- No metastatic carcinoma identified (0/3).

P: Lymph node, right neck, level 2, dissection

- No metastatic carcinoma identified (0/15).

Q: Lymph node, right neck, level 3, dissection

- No metastatic carcinoma identified (0/9).

R: Lymph node, right neck, level 4, dissection

- No metastatic carcinoma identified (0/12).

S: Floor of mouth, excision

- Invasive squamous carcinoma, poorly differentiated, 2.4 cm diameter, 0.7 cm depth.

- Vascular invasion: not identified.

[page 2 of 4]
- Surgical margins: negative but close (closest approach is 0.1 cm in S3).
- Associated squamous carcinoma in situ (S7).
- Lymph node with this specimen: no metastatic carcinoma identified (0/1).
- AJCC Stage: pT2 pN0 pMx

Intraoperative Consult Diagnosis:

Frozen section consultation was requested by Dr.

FSA1: Left tongue base, biopsy

- Benign squamous mucosa

FSB1: Midline deep margin, biopsy

- No tumor seen

FSC1: Right posterior tongue mucosal margin, biopsy

- No tumor seen

FSD1: Right floor of mouth anterior margin, biopsy

- No tumor seen

FSE1: Mid tongue mucosal margin, biopsy

- No tumor seen

FSF1: Left mid lateral tongue margin, biopsy

- No tumor seen

FSG1: Anterior left floor of mouth mucosa (adjacent to Tooth #21), biopsy

- No tumor seen

FSH1: Left posterior tongue mucosa, biopsy

- No tumor seen

FSI1: Midline anterior floor of mouth mucosa, biopsy

- No tumor seen

Frozen Section Pathologist:

Clinical History:

squamous cell carcinoma of mouth.

Gross Description:

Container A consists of a 3 x 2 x 2 mm in aggregate red/tan soft tissue fragments submitted in block FSA1, [REDACTED]

Container B consists of an 8 x 5 x 5 mm red/tan soft tissue fragment submitted in block FSB1, [REDACTED]

Container C consists of a 4 x 4 x 3 mm red/tan soft tissue fragment submitted in block FSC1, [REDACTED]

Container D consists of a 5 x 2 x 2 mm red/tan soft tissue fragment submitted in block FSD1, [REDACTED]

Container E consists of a 5 x 4 x 3 mm red/tan soft tissue fragment submitted in block FSE1, [REDACTED]

Container F consists of a 6 x 4 x 4 mm red/tan soft tissue fragment submitted in block FSF1, [REDACTED]

Container G consists of a 4 x 3 x 2 mm red/tan soft tissue fragment submitted in block FSG1, [REDACTED]

Container H consists of a 3 x 3 x 2 mm red/tan soft tissue fragment submitted in block FSH1, [REDACTED]

Container I consists of a 4 x 3 x 2 mm red/tan soft tissue fragment submitted in block FSI1, [REDACTED]

Container J is additionally labeled "L neck, Level 2." It consists of a 4.8 x 4.2 x 1.7 cm yellow/tan fibroadipose tissue fragment with multiple lymph node candidates.

[page 3 of 4]
Block summary:

J1 - four lymph node candidates
J2 - one lymph node candidate, bisected
J3 - three lymph node candidates
J4 - fibrovascular tissue with possible lymph node candidates
Scant fibromuscular tissue remains.

Container K is additionally labeled "L neck Level 3." It consists of a 3.4 x 2.8 x 1.3 cm yellow/tan fibroadipose tissue with multiple lymph node candidates.

Block summary:

K1 - one lymph node candidate, bisected
K2 - two lymph node candidates
K3 - fibrovascular tissue with multiple lymph node candidates
Fibromuscular tissue remains.

Container L is additionally labeled "left neck Level 4." It holds a 4.2 x 3.5 x 1.3 cm aggregate of yellow/tan fibroadipose tissue with multiple lymph node candidates.

Block summary:

L1 - three lymph node candidates
L2 - four lymph node candidates
Fibromuscular tissue remains.

Container M is additionally labeled "Level 1A, bilateral." It holds a 1.5 x 2.4 x 1.2 cm yellow/tan fibroadipose tissue.

Block summary:

M1 - three lymph node candidates
M2 - fibrovascular remnant, [REDACTED]

Container N is additionally labeled "L neck, Level 1B." It holds a 4.9 x 5.1 x 2.6 cm aggregate of yellow/tan fibroadipose tissue with multiple lymph node candidates and submandibular gland.

Block Summary:

N1 - piece of submandibular gland with fibrovascular tissue
N2 - three lymph node candidates
N3 - three lymph node candidates and submandibular gland
N4 - one lymph node candidate and additional section of submandibular gland Submandibular tissue remains.

Container O is additionally labeled "R Level 1B." It holds a 4.7 x 4.2 x 2.3 cm aggregate of yellow/tan fibroadipose tissue, submandibular gland and lymph node candidates. Sectioning of the submandibular gland demonstrates tan parenchyma without masses.

Block summary:

O1 - one lymph node candidate, bisected
O2 - two lymph node candidates and sample of submandibular gland
O3 - remnant fibrovascular tissue with possible lymph node candidates
O4 - sample of submandibular gland and additional fibrovascular tissue
Remnant submandibular gland remains.

Container P is additionally labeled "left neck Level 2." It holds a 4.3 x 3.6 x 1.2 cm aggregate of fibroadipose tissue with multiple lymph node candidates.

Block Summary:

P1 - two lymph node candidates
P2 - four lymph node candidates
P3 - three lymph node candidates
Fibrofatty remnant remains.

Container Q is additionally labeled "R neck Level 3." It holds a 4.1 x 3.3 x 1.7 cm aggregate of yellow/tan fibroadipose tissue with lymph node candidates.

Block Summary:

Q1 - four lymph node candidates
Q2 - three lymph node candidates
Q3, Q4 - fibrovascular remnant with possible lymph node candidates
Fibroadipose tissue remains.

[page 4 of 4]
Container R is additionally labeled "R neck Level 4." It holds a 5.4 x 3.6 x 2.2 cm aggregate of yellow/tan fibroadipose tissue with lymph node candidates.

Block Summary:

R1 - three lymph node candidates

R2 - three lymph node candidates

R3 - two lymph node candidates

Fatty tissue and muscle remains.

Container S is additionally labeled "floor of mouth, short/ant., long/lateral."

Specimen fixation: formalin

Type of specimen: floor of mouth resection

Size of specimen: 4.0 x 3.3 x 1.9 cm

Laterality: The specimen is described as floor of mouth.

Orientation of specimen: short=anterior, long="lateral" (which is presumed lateral)

Inking: anterior=blue, posterior=black. The specimen was sectioned from "lateral" (presumed lateral) to medial. The deep aspect is inked red.

Description of specimen: Received is a brown/tan soft tissue fragment with a white/tan ulcerated mucosal surface on the anterior aspect. This island of mucosa is 3.9 x 1.8 cm in greatest dimensions.

Tumor description: Tumor involves the mucosa and is white/tan, firm and rubbery.

Location of tumor: floor of mouth

Tumor size: 2.3 cm from lateral (long stitch) to medial, 0.7 cm superficial to deep, 0.8 cm from mucosal surface to red inked non-mucosal surface

Distance of tumor to surgical margins: The mass is 0.5 cm from the black inked posterior margin, 0.5 cm from the red inked margin opposite mucosa, 1.3 cm from the medial tip, 0.7 cm from the lateral tip (long stitch).

Presence/absence of bone involvement: n/a

Description of remainder of tissue: normal tan/brown fibromuscular and adipose tissue

Tissue submitted for special investigations: none

Lymph nodes: per block summary

Digital photograph taken: yes

Block summary:

(Inking: anterior (side of short stitch)=blue, posterior=black, the mucosa goes from anterior to the lateral surface and the opposite lateral cut surface is inked red; The specimen was sectioned from lateral (long stitch) to medial).

S1 - lateral tip

S2 - medial tip

S3-S12 - sequential sections from lateral (long stitch) to medial

Light Microscopy:

Light microscopic examination is performed by Dr.

The frozen section diagnoses are confirmed.

Signature

Resident Physician:

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 84b81591-f4db-4b66-996c-5bfc629d8500 (TCGA-BA-5556.8DC6CF68-6A19-4661-BD36-6D4EF4093D2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).